Surgical pathology report (de-identified scan), TCGA case TCGA-D7-5579, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-5579-01A (Primary Tumor).

Badanie:

Materiały:

Materiał pobrano:

Materiał otrzymano:

Rozpoznanie kliniczne

TCGA-D7-5579

Badanie wykonano

Opis makroskopowy:

W nadesłanym materiale żołądek - po rozcięciu wzdłuż krzywizny większej o wymiarach; 19 x 16 cm z siecią o wymiarach; 20 x 10 cm.

W trzonie pogrubienie ściany na obszarze o wymiarach; 10 x 11 x 2 cm.

Odległość do granicy proksymalnej 4 cm, dystalnej 3 cm.

Opis mikroskopowy:

Adenocarcinoma mucocellulare et mucinosum ventriculi (G3, typ rozlany) - infiltratio parietis totae ventriculi et omenti maioris et minoris.

Naciek dochodzi do dystalnej linii cięcia.

proksymalna linia cięcia bez zmian nowotworowych.

Węzły chłonne - metastases in lymphonodis (XI/XII)

Wynik badania

Adenocarcinoma mucocellulare et mucinodism ventriculi.

Metastases in lymphonodis (XI/XII).

(G3, pT3, pN2).

Naciek dochodzi do dystalnej linii cięcia.

MUCINOUS PARTIALLY SIGNET-RING TYPE ADENOCARCINOMA OF THE STOMACH.
11 METASTATIC LYMPH NODES (OUT OF 12)

Source: NCI Genomic Data Commons file e9d08c4a-d2f2-43d7-aee8-dc151c1eecbf (TCGA-D7-5579.EF4ACB6F-A507-4ADC-97E3-0314C8A3E898.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).